Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96G, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96G-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

tumor: 5.0 x 4.0 x 4.5 cm

Diagnosis:

Type A/B Thymoma (dominant Type is B1)

pT2

Masaoka: II.1

Immunohistochemistry

epithelial cells positive for: CK5/6
positive membrane staining for EGFR

CD1a, CD5, CD99-positive immature T-lymphocytes

ICD-O 3
Thymoma, type AB,
malignant 8582/3
Site: Thymus C37.9
QW 4/7/14

Source: NCI Genomic Data Commons file 18eb2bdd-5e6c-4a0f-9788-884c7e1e3c2c (TCGA-ZB-A96G.17576F98-1EBE-460F-983D-D088D9B4F235.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).